Gene-level copy-number profile of tumor specimen TCGA-13-0764-01A from TCGA case TCGA-13-0764, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 62.9 years (22,965 days).
Specimen TCGA-13-0764-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0c0fe76e-4298-462c-9354-f7e92391a135.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0764-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e549f2b-41e6-4a19-8996-3c1b90d912eb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 680; copy number 2: 6,303; copy number 3: 17,224; copy number 4: 20,136; copy number 5: 7,661; copy number 6: 4,311; copy number 7: 1,882; copy number 8: 753; copy number 9: 210; copy number 10: 372; copy number 11: 60; copy number 12: 73; copy number 14: 15; copy number 15: 90; copy number 16: 6; copy number 19: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0764-01A-03D-0356-01): tumor purity 0.77, ploidy 3.93, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,304,047–60,304,151, 1 gene: RNU6-806P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 859 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,350,934–41,242,154, 136 genes, copy number 9–15 (within-gene range 4–15) (broad region; genes not listed).
- chr1:117,640,812–118,264,489, 9 genes, copy number 9: VDAC2P3, AL390877.1, AL390877.2, PNRC2P1, GDAP2, WDR3, SPAG17, AL391557.1, RNA5SP56.
- chr3:88,149,959–90,261,708, 15 genes, copy number 14: C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:145,523,538–145,685,092, 2 genes, copy number 9: LARP7P4, GM2AP1.
- chr4:87,160,103–87,531,061, 13 genes, copy number 10: KLHL8, AC092658.1, GAPDHP60, AC108516.1, MIR5705, HSD17B13, AC108516.2, HSD17B11, RN7SL681P, AC112250.1, NUDT9, AC112250.2, SPARCL1.
- chr4:87,608,529–87,616,873, 1 gene, copy number 10: DSPP.
- chr6:39,792,298–39,904,877, 1 gene, copy number 9 (within-gene range 7–9): DAAM2.
- chr6:39,881,804–48,795,513, 211 genes, copy number 9–12 (broad region; genes not listed).
- chr6:57,314,805–58,438,364, 16 genes, copy number 10 (within-gene range 6–10): PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr6:61,240,898–65,707,226, 32 genes, copy number 9–10 (within-gene range 6–10): AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr16:74,447,427–74,607,144, 1 gene, copy number 11 (within-gene range 2–11): GLG1.
- chr16:74,552,251–75,861,157, 50 genes, copy number 11: AC009153.1, HSPE1P7, RFWD3, TMPOP2, MLKL, FA2H, AC009132.1, WDR59, ZNRF1, AC099508.1, LDHD, AC099508.2, ZFP1, AC009078.1, CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P, CFDP1, AC009054.1, AC009054.2, AC009163.2, AC009163.5, AC009163.7, TMEM170A, AC009163.4, CHST6, AC009163.1, AC009163.6, TMEM231P1, AC009163.3, CHST5, TMEM231, AC025287.1, AC025287.2, GABARAPL2, AC025287.3, ADAT1, KARS1, AC025287.5, TERF2IP, AC025287.4, DUXB, RN7SL520P, ATP5PBP7, CPHXL, AC105430.1, RNA5SP430.
- chr16:78,123,243–78,355,834, 5 genes, copy number 10: AC079414.3, AC009044.1, WWOX-AS1, AC106743.1, LSM3P5.
- chr18:1,883,524–2,489,426, 1 gene, copy number 10 (within-gene range 8–10): AP005230.1.
- chr18:2,506,628–3,478,978, 37 genes, copy number 10: AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,571,215–3,771,430, 6 genes, copy number 10: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2.
- chr18:36,829,106–37,232,172, 1 gene, copy number 9 (within-gene range 6–9): KIAA1328.
- chr18:37,234,119–43,499,836, 42 genes, copy number 9: AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1, AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, AC087683.3, LINC00907, RNA5SP454, AC084335.1, RIT2, AC100779.1, SYT4, AC022743.1.
- chr18:44,970,082–49,851,059, 107 genes, copy number 10 (broad region; genes not listed).
- chr18:49,871,555–49,871,666, 1 gene, copy number 10: Y_RNA.
- chr19:28,435,388–32,387,667, 69 genes, copy number 9–19 (within-gene range 3–19) (broad region; genes not listed).
- chr19:38,433,691–39,032,785, 32 genes, copy number 10 (within-gene range 4–10): RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1.
- chr20:12,950,288–18,113,579, 70 genes, copy number 9 (broad region; genes not listed).
- chr20:18,137,863–18,143,169, 1 gene, copy number 9: PET117.

Autosomal genes at a single copy (total copy number 1): 680. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
